Somatic mutation profile of tumor specimen TCGA-14-1396-01A (aliquot TCGA-14-1396-01A-01W-0611-08) from TCGA case TCGA-14-1396, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 78.7 years (28,753 days).
Specimen TCGA-14-1396-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 28710c63-13af-46c3-b4a1-23e47e1c37fe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-14-1396-10A (Blood Derived Normal), aliquot TCGA-14-1396-10A-01W-0611-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b6ccb27d-4af1-42f9-a2ea-d5fdf8127830

The open-access MAF lists 193 somatic variants for this specimen: 132 protein-altering or splice-affecting, 57 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 107, Silent 57, Nonsense Mutation 15, Splice Site 4, Frame Shift Del 2, Intron 2, Frame Shift Ins 2, RNA 1, In Frame Del 1, 5'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- L1CAM | c.1672C>T p.R558* | Nonsense Mutation (SNP) | VAF 7/48 reads (15%) | catalogued as rs1557091773, CM970857, COSV62828861; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3R1 | c.1214_1216del p.I405del (on ENST00000521381 / NM_181523.3; = p.I135del on NM_181504.4) | In Frame Del (DEL) | VAF 32/57 reads (56%) | hotspot (GDC flag); called by pindel, varscan2
- TP53 | c.272G>A p.W91* | Nonsense Mutation (SNP) | VAF 15/25 reads (60%) | hotspot (GDC flag); catalogued as COSV52734595, COSV53139118; called by muse, mutect2, varscan2
- ABCB4 | c.1258C>T p.Q420* | Nonsense Mutation (SNP) | VAF 8/119 reads (7%) | catalogued as COSV99709886; called by muse, mutect2
- ABL2 | c.3349C>A p.L1117I (on ENST00000502732 / NM_007314.4; = p.L1102I on NM_005158.5) | Missense Mutation (SNP) | VAF 37/900 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100772542; called by muse, mutect2
- ADCY7 | c.776G>A p.R259H | Missense Mutation (SNP) | VAF 65/132 reads (49%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as rs545059286, COSV54271135; called by muse, mutect2, varscan2
- ADGRG4 | c.3941C>T p.S1314L | Missense Mutation (SNP) | VAF 116/258 reads (45%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as rs751562884, COSV54950446; called by muse, varscan2
- ADPGK | c.1464C>A p.F488L | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100295160; called by muse, mutect2
- AGT | c.1075C>A p.L359I | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.331); catalogued as COSV100794236; called by muse, varscan2
- ALDH6A1 | c.1079C>A p.T360N | Missense Mutation (SNP) | VAF 18/321 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.446); catalogued as COSV100620825; called by muse, mutect2
- ANK1 | c.2674A>T p.S892C | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.572); catalogued as COSV99224314; called by muse, mutect2, varscan2
- ARHGAP32 | c.3727G>T p.D1243Y (on ENST00000310343 / NM_001378025.1; = p.D894Y on NM_014715.4) | Missense Mutation (SNP) | VAF 76/648 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100087149; called by muse, varscan2
- ATRX | c.5359G>A p.G1787S | Missense Mutation (SNP) | VAF 23/153 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100970213; called by muse, varscan2
- BMPR1B | c.1197C>A p.D399E | Missense Mutation (SNP) | VAF 25/534 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99215497; called by muse, mutect2
- C6 | c.130C>T p.Q44* | Nonsense Mutation (SNP) | VAF 34/132 reads (26%) | catalogued as COSV99666673; called by muse, varscan2
- CCDC80 | c.1099C>T p.R367W | Missense Mutation (SNP) | VAF 27/185 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV52816341; called by muse, mutect2, varscan2
- CCNB3 | c.899G>A p.R300K | Missense Mutation (SNP) | VAF 63/1307 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs954441191, COSV52082067; called by muse, mutect2
- CCT6B | c.1148C>T p.T383I | Missense Mutation (SNP) | VAF 23/152 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.168); catalogued as COSV100030482; called by muse, mutect2, varscan2
- CD96 | c.1390G>A p.E464K (on ENST00000283285 / NM_198196.3; = p.E448K on NM_005816.5) | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT tolerated (0.07); PolyPhen benign (0.092); catalogued as COSV51914800; called by muse, mutect2, varscan2
- CDCP1 | c.2464G>T p.D822Y | Missense Mutation (SNP) | VAF 17/301 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.568); catalogued as COSV56106503, COSV99943894; called by muse, mutect2
- CIT | c.6029C>T p.A2010V | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.07); catalogued as COSV55861437; called by muse, mutect2, varscan2
- CLBA1 | c.406G>A p.A136T | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.046); catalogued as COSV101120989; called by muse, mutect2, varscan2
- CMYA5 | c.9514C>T p.P3172S | Missense Mutation (SNP) | VAF 19/445 reads (4%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.481); catalogued as rs867567955, COSV101483935; called by muse, mutect2
- COL2A1 | c.4411G>A p.G1471R | Missense Mutation (SNP) | VAF 34/474 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56742634; called by muse, mutect2
- DERA | c.592A>C p.T198P | Missense Mutation (SNP) | VAF 60/724 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as COSV101397318; called by muse, mutect2
- DHX15 | c.1081-1G>C p.X361_splice | Splice Site (SNP) | VAF 12/28 reads (43%) | catalogued as COSV100391209; called by muse, mutect2, varscan2
- DHX15 | c.1081-2A>T p.X361_splice | Splice Site (SNP) | VAF 12/28 reads (43%) | catalogued as COSV100391211, COSV61026543; called by muse, mutect2, varscan2
- EPHB2 | c.1466C>T p.P489L | Missense Mutation (SNP) | VAF 34/168 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.071); catalogued as COSV101006822; called by muse, mutect2, varscan2
- EWSR1 | c.1096C>T p.Q366* | Nonsense Mutation (SNP) | VAF 11/354 reads (3%) | catalogued as COSV100131031; called by muse, mutect2
- FECH | c.364C>A p.Q122K | Missense Mutation (SNP) | VAF 41/956 reads (4%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.589); catalogued as CM032225, COSV50493845; called by muse, mutect2
- FMN2 | c.4105G>A p.G1369R | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100143597; called by muse, varscan2
- FPGT | c.1207C>T p.P403S | Missense Mutation (SNP) | VAF 24/135 reads (18%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as COSV100907074, COSV100907141; called by muse, varscan2
- GABRB1 | c.710T>A p.F237Y | Missense Mutation (SNP) | VAF 147/419 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99780540; called by muse, mutect2, varscan2
- GALNT14 | c.1456G>A p.A486T | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.053); catalogued as rs149431826; called by muse, mutect2, varscan2
- GEMIN5 | c.2099C>G p.S700* | Nonsense Mutation (SNP) | VAF 9/126 reads (7%) | catalogued as COSV53559772, COSV99593689; called by muse, mutect2
- GLS | c.1712+1G>T p.X571_splice | Splice Site (SNP) | VAF 225/675 reads (33%) | catalogued as COSV100289812; called by muse, mutect2, varscan2
- GRB14 | c.563G>A p.R188K | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.821); catalogued as COSV99813758; called by muse, mutect2, varscan2
- GTF3C3 | c.2251C>A p.H751N | Missense Mutation (SNP) | VAF 22/160 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.946); catalogued as COSV99826542; called by muse, mutect2, varscan2
- HINT1 | c.292G>A p.V98M | Missense Mutation (SNP) | VAF 142/417 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.583); catalogued as COSV100401112; called by muse, mutect2, varscan2
- HLCS | c.718G>A p.G240R | Missense Mutation (SNP) | VAF 56/206 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751038449, COSV100357952; called by muse, mutect2, varscan2
- IFIT5 | c.1397C>T p.P466L | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.979); catalogued as COSV100877929; called by muse, varscan2
- IGF2R | c.3218C>T p.T1073I | Missense Mutation (SNP) | VAF 12/304 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100807033; called by muse, mutect2
- IKZF1 | c.505G>A p.G169R | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100498081; called by muse, mutect2, varscan2
- IL12RB1 | c.691G>A p.V231I | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0.068); catalogued as rs140762977; called by muse, mutect2, varscan2
- IQCH | c.2687C>T p.T896I | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.038); catalogued as COSV100245498; called by muse, mutect2, varscan2
- IRF8 | c.177C>T p.A59= | Splice Region (SNP) | VAF 26/46 reads (57%) | catalogued as COSV99236164; called by muse, mutect2, varscan2
- ITGAD | c.487C>T p.Q163* | Nonsense Mutation (SNP) | VAF 4/35 reads (11%) | catalogued as rs1213449621, COSV101210364; called by muse, mutect2, varscan2
- KLHL4 | c.1592A>G p.H531R | Missense Mutation (SNP) | VAF 50/573 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV100909254; called by muse, mutect2
- LGSN | c.1185C>G p.I395M | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV101040341; called by muse, varscan2
- LRCH1 | c.851T>G p.F284C | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100243356; called by muse, mutect2
- LRP2 | c.4093G>T p.V1365F | Missense Mutation (SNP) | VAF 58/467 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.219); catalogued as COSV99786940; called by muse, mutect2, varscan2
- LRRK2 | c.5908C>G p.L1970V | Missense Mutation (SNP) | VAF 198/310 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as rs369497805, COSV100109479, COSV100110880; called by muse, mutect2, varscan2
- MACF1 | c.3754C>A p.L1252M | Missense Mutation (SNP) | VAF 11/144 reads (8%) | catalogued as COSV100483052; called by muse, mutect2
- MCM3 | c.1638G>T p.Q546H (on ENST00000229854 / NM_001366374.2; = p.Q536H on NM_002388.6 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/244 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as COSV100008630; called by muse, mutect2
- MCM6 | c.1333G>A p.E445K | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1245959167, COSV99918810; called by mutect2, varscan2
- METTL2A | c.881G>A p.G294D | Missense Mutation (SNP) | VAF 15/243 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100274143; called by muse, mutect2
- MOSPD2 | c.60C>A p.F20L | Missense Mutation (SNP) | VAF 34/378 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100146433; called by muse, mutect2
- MOXD1 | c.1568C>T p.A523V | Missense Mutation (SNP) | VAF 163/331 reads (49%) | SIFT tolerated (0.43); PolyPhen benign (0.113); catalogued as COSV100381319; called by muse, mutect2, varscan2
- MRGPRD | c.331G>T p.V111L | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV100482949; called by muse, mutect2, varscan2
- MUC16 | c.18763C>G p.P6255A | Missense Mutation (SNP) | VAF 65/546 reads (12%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as COSV67467336; called by muse, mutect2, varscan2
- MYO9A | c.16G>A p.G6R | Missense Mutation (SNP) | VAF 9/187 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV61858323; called by muse, mutect2
- NF1 | c.3163C>T p.Q1055* | Nonsense Mutation (SNP) | VAF 36/86 reads (42%) | catalogued as rs866069972, CM040782, COSV62192268; called by muse, mutect2, varscan2
- NFIB | c.481G>T p.A161S | Missense Mutation (SNP) | VAF 10/216 reads (5%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.587); catalogued as COSV101100259; called by muse, mutect2
- NHSL2 | c.2047G>A p.G683S (on ENST00000510661; = p.G1049S on NM_001013627.2) | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.003); catalogued as rs755673772, COSV65453660, COSV65453776; called by muse, mutect2, varscan2
- NMUR2 | c.1157C>T p.S386L | Missense Mutation (SNP) | VAF 53/217 reads (24%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as COSV99676688; called by muse, mutect2, varscan2
- NOX4 | c.352G>A p.V118M | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.123); catalogued as rs768559870, COSV54466141; called by muse, mutect2, varscan2
- NWD1 | c.2165C>T p.T722M | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs145011343; called by muse, mutect2, varscan2
- OR2F1 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 88/539 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.036); catalogued as rs140718215, COSV67331755; called by muse, mutect2, varscan2
- OR2M4 | c.701G>A p.R234H | Missense Mutation (SNP) | VAF 123/211 reads (58%) | SIFT tolerated (0.1); PolyPhen benign (0.021); catalogued as rs1192709932, COSV60708803, COSV60709747; called by muse, mutect2, varscan2
- OR5D13 | c.312T>A p.C104* | Nonsense Mutation (SNP) | VAF 42/128 reads (33%) | catalogued as COSV100686763; called by muse, mutect2, varscan2
- OR5P3 | c.571C>T p.H191Y | Missense Mutation (SNP) | VAF 14/256 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); catalogued as COSV100103041; called by muse, mutect2
- OR5T1 | c.939C>G p.I313M | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (0.89); PolyPhen benign (0.005); catalogued as COSV100478795; called by muse, mutect2, varscan2
- OR8K1 | c.181C>A p.L61I | Missense Mutation (SNP) | VAF 9/155 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.84); catalogued as COSV99687146; called by muse, mutect2
- PCDH18 | c.2218G>A p.E740K | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.833); catalogued as rs903210960, COSV61267146; called by muse, mutect2, varscan2
- PCDH18 | c.1388C>T p.P463L | Missense Mutation (SNP) | VAF 25/764 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100787099; called by muse, mutect2
- PDE4D | c.85C>A p.P29T | Missense Mutation (SNP) | VAF 235/468 reads (50%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV101550421; called by muse, mutect2, varscan2
- PLD5 | c.403G>A p.G135S (on ENST00000442594; = p.G73S on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/139 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.972); catalogued as COSV100139183; called by muse, mutect2, varscan2
- PNPLA3 | c.353T>C p.L118P | Missense Mutation (SNP) | VAF 92/357 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53380373, COSV99336989; called by muse, mutect2, varscan2
- PPM1E | c.779T>G p.L260R | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV100375948; called by muse, mutect2, varscan2
- PRTG | c.2300C>T p.A767V | Missense Mutation (SNP) | VAF 42/355 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.71); catalogued as COSV101221310; called by muse, varscan2
- PTCH1 | c.4248C>A p.F1416L | Missense Mutation (SNP) | VAF 33/165 reads (20%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); catalogued as rs1564004573, COSV100107803; called by muse, mutect2, varscan2
- PTGFRN | c.1105G>A p.G369S | Missense Mutation (SNP) | VAF 192/343 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101277265; called by muse, varscan2
- PUM1 | c.3295G>A p.D1099N | Missense Mutation (SNP) | VAF 47/274 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.08); catalogued as rs1335543720, COSV99927608; called by muse, mutect2, varscan2
- RANBP17 | c.3059G>A p.R1020K | Missense Mutation (SNP) | VAF 41/213 reads (19%) | SIFT tolerated (0.58); PolyPhen benign (0.009); catalogued as COSV101206131; called by muse, varscan2
- RFC3 | c.583G>T p.V195L | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.06); catalogued as rs41553716, COSV101197800; called by muse, mutect2, varscan2
- RFC4 | c.470C>T p.S157L | Missense Mutation (SNP) | VAF 279/1068 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.216); catalogued as COSV56218395; called by muse, varscan2
- RHAG | c.563T>C p.I188T | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.083); catalogued as rs1483010643, COSV100006412; called by muse, mutect2, varscan2
- RPS6KA2 | c.1687G>A p.A563T | Missense Mutation (SNP) | VAF 140/357 reads (39%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); catalogued as COSV55818538; called by muse, mutect2, varscan2
- RPS6KA6 | c.1564G>A p.D522N | Missense Mutation (SNP) | VAF 10/158 reads (6%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV99424291; called by muse, mutect2
- RRBP1 | c.4171C>A p.L1391M (on ENST00000377813 / NM_001365613.2; = p.L958M on NM_004587.3) | Missense Mutation (SNP) | VAF 42/318 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99853683; called by muse, mutect2
- SAMD9L | c.946T>G p.C316G | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100560418; called by muse, varscan2
- SCYL3 | c.1596G>A p.W532* (on ENST00000367770; = p.W478* on NM_020423.7) | Nonsense Mutation (SNP) | VAF 39/103 reads (38%) | catalogued as COSV53677569, COSV99609500; called by muse, mutect2, varscan2
- SF3B3 | c.158T>A p.L53Q | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as COSV100209649; called by muse, mutect2, varscan2
- SLC18A1 | c.1261C>T p.R421C | Missense Mutation (SNP) | VAF 35/137 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs141967734; called by muse, mutect2, varscan2
- SLC29A4 | c.1042G>A p.V348M | Missense Mutation (SNP) | VAF 108/177 reads (61%) | SIFT tolerated (0.11); PolyPhen benign (0.052); catalogued as rs370235014; called by muse, mutect2, varscan2
- SLC9A4 | c.916G>A p.V306I | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.572); catalogued as rs541859382, COSV54828553; called by muse, mutect2, varscan2
- SP1 | c.1774C>T p.Q592* (on ENST00000327443 / NM_138473.3; = p.Q585* on NM_003109.1) | Nonsense Mutation (SNP) | VAF 7/85 reads (8%) | catalogued as rs867126046, COSV100540453; called by muse, mutect2
- SPARCL1 | c.1156C>T p.Q386* | Nonsense Mutation (SNP) | VAF 6/52 reads (12%) | catalogued as COSV99215346; called by muse, mutect2, varscan2
- STAT2 | c.1171G>A p.G391R | Missense Mutation (SNP) | VAF 15/148 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.985); catalogued as COSV100028671; called by muse, mutect2, varscan2
- STYXL2 | c.601C>T p.Q201* | Nonsense Mutation (SNP) | VAF 105/329 reads (32%) | catalogued as rs970594005, COSV99608726; called by muse, mutect2, varscan2
- TENM1 | c.1436C>A p.T479K | Missense Mutation (SNP) | VAF 83/526 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV100949328; called by muse, mutect2, varscan2
- TEX11 | c.2281G>A p.E761K (on ENST00000344304; = p.E746K on NM_031276.3) | Missense Mutation (SNP) | VAF 72/266 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); catalogued as COSV60230120; called by muse, mutect2, varscan2
- THAP8 | c.32C>A p.S11Y | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as COSV53078482, COSV53078706; called by muse, mutect2
- TLR6 | c.1459G>A p.D487N | Missense Mutation (SNP) | VAF 67/195 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.078); catalogued as rs754692374, COSV101126247; called by muse, mutect2, varscan2
- TLR8 | c.2327G>T p.C776F (on ENST00000218032 / NM_138636.5; = p.C794F on NM_016610.4) | Missense Mutation (SNP) | VAF 10/218 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV99486836; called by muse, mutect2
- TMTC4 | c.1529G>A p.R510K (on ENST00000376234 / NM_001350577.2; = p.R529K on NM_032813.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 106/411 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.241); catalogued as COSV100168513; called by muse, mutect2, varscan2
- TPTE2 | c.1205T>C p.I402T (on ENST00000400230 / NM_199254.2; = p.I325T on NM_130785.3) | Missense Mutation (SNP) | VAF 211/309 reads (68%) | SIFT tolerated (0.3); PolyPhen benign (0.058); catalogued as COSV99689844; called by muse, mutect2, varscan2
- TRIM2 | c.110C>T p.P37L (on ENST00000437508; = p.P64L on NM_015271.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 67/125 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100107653; called by muse, mutect2, varscan2
- TRIM24 | c.2697_2701del p.K899Nfs*5 (on ENST00000343526 / NM_015905.3; = p.K865Nfs*5 on NM_003852.4) | Frame Shift Del (DEL) | VAF 75/222 reads (34%) | catalogued as rs760057002; called by pindel, varscan2
- TRPA1 | c.393G>T p.M131I | Missense Mutation (SNP) | VAF 30/978 reads (3%) | SIFT tolerated (0.13); PolyPhen benign (0.057); catalogued as COSV100083446; called by muse, mutect2
- TSC1 | c.2443A>T p.K815* | Nonsense Mutation (SNP) | VAF 313/381 reads (82%) | catalogued as COSV100051324; called by muse, mutect2, varscan2
- UGT1A9 | c.649C>T p.H217Y | Missense Mutation (SNP) | VAF 32/1155 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV100692063; called by muse, mutect2
- WDFY3 | c.6250C>A p.Q2084K | Missense Mutation (SNP) | VAF 23/219 reads (11%) | SIFT tolerated (0.89); PolyPhen benign (0.013); catalogued as COSV99882425; called by muse, mutect2, varscan2
- WDR17 | c.1937A>G p.D646G | Missense Mutation (SNP) | VAF 73/86 reads (85%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1229951392, COSV99707016; called by muse, mutect2, varscan2
- WNK3 | c.4178C>A p.S1393* | Nonsense Mutation (SNP) | VAF 36/70 reads (51%) | catalogued as COSV63611806, COSV63615042; called by muse, mutect2, varscan2
- ZBTB40 | c.373G>T p.V125L | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.079); catalogued as COSV100988839; called by muse, mutect2
- ZC3H12B | c.1649G>T p.G550V | Missense Mutation (SNP) | VAF 366/565 reads (65%) | SIFT deleterious (0.01); PolyPhen benign (0.12); catalogued as COSV100161549; called by muse, mutect2, varscan2
- ZNF626 | c.443A>G p.D148G | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.167); catalogued as COSV101656954; called by muse, mutect2, varscan2
- ZNF699 | c.1174A>G p.K392E | Missense Mutation (SNP) | VAF 6/126 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as COSV58024990; called by muse, mutect2
- ZNF77 | c.1370C>A p.T457N | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.438); catalogued as COSV100094350; called by muse, mutect2
- AC006059.2 | c.2163G>T p.Q721H | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by mutect2, varscan2
- CTNS | c.236del p.P79Lfs*4 | Frame Shift Del (DEL) | VAF 5/55 reads (9%) | called by mutect2, pindel
- FZD6 | c.655A>C p.T219P | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- GOLGA3 | c.358G>C p.A120P | Missense Mutation (SNP) | VAF 26/46 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); called by mutect2, varscan2
- GRIN2C | c.1907C>A p.A636D | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- JAK2 | c.1310dup p.L437Ffs*12 | Frame Shift Ins (INS) | VAF 4/36 reads (11%) | called by pindel, varscan2
- KCNG4 | c.200dup p.R68Qfs*36 | Frame Shift Ins (INS) | VAF 5/48 reads (10%) | called by pindel, varscan2
- SPTB | c.1949A>G p.E650G | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); called by mutect2, varscan2
- TAC4 | c.311-16_313del p.X104_splice | Splice Site (DEL) | VAF 32/346 reads (9%) | called by mutect2, pindel
- TEX2 | c.799C>T p.P267S | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- TMEM187 | c.760C>T p.H254Y | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.107); called by muse, varscan2
- VPS72 | c.990T>A p.H330Q | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- ABCA13 | c.207C>T p.P69= | Silent (SNP) | VAF 30/214 reads (14%) | catalogued as COSV101330213, COSV70025913; called by muse, mutect2, varscan2
- AC008397.2 | c.633C>T p.D211= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs760869430, COSV53205187; called by muse, mutect2
- ACTBL2 | c.600C>T p.N200= | Silent (SNP) | VAF 67/368 reads (18%) | catalogued as COSV101379258; called by muse, mutect2, varscan2
- ARHGAP6 | c.1752C>T p.S584= | Silent (SNP) | VAF 16/392 reads (4%) | catalogued as COSV100272472; called by muse, mutect2
- CACNA1S | c.4650G>A p.K1550= | Silent (SNP) | VAF 35/611 reads (6%) | catalogued as COSV100754753; called by muse, mutect2
- CDH12 | c.1089C>A p.G363= | Silent (SNP) | VAF 10/94 reads (11%) | catalogued as COSV101201811; called by muse, mutect2, varscan2
- COL17A1 | c.558C>T p.P186= | Silent (SNP) | VAF 125/863 reads (14%) | catalogued as COSV100793086; called by muse, mutect2, varscan2
- CRYBA2 | c.345C>T p.N115= | Silent (SNP) | VAF 34/70 reads (49%) | catalogued as rs1215821075, COSV55387808, COSV99838051; called by muse, mutect2, varscan2
- CRYGN | c.366G>A p.R122= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as rs1563081547, COSV100484699; called by muse, mutect2, varscan2
- CUL9 | c.5640C>A p.L1880= | Silent (SNP) | VAF 38/404 reads (9%) | catalogued as COSV99334959; called by muse, mutect2
- CYP17A1 | c.1212G>A p.K404= | Silent (SNP) | VAF 98/580 reads (17%) | catalogued as COSV100882081; called by muse, mutect2, varscan2
- DLEC1 | c.1431G>T p.L477= | Silent (SNP) | VAF 36/552 reads (7%) | catalogued as COSV100341682; called by muse, mutect2
- DOCK6 | c.759C>A p.P253= | Silent (SNP) | VAF 26/407 reads (6%) | catalogued as rs566869284, COSV99624983; called by muse, mutect2
- DOP1B | c.3426G>A p.E1142= | Silent (SNP) | VAF 6/11 reads (55%) | catalogued as rs771615988, COSV101215133; called by muse, varscan2
- DPH1 | c.972C>T p.F324= | Silent (SNP) | VAF 110/326 reads (34%) | catalogued as COSV99559455; called by muse, varscan2
- EXOC2 | c.66G>A p.T22= | Silent (SNP) | VAF 128/209 reads (61%) | catalogued as rs1561955902, COSV57869586; called by muse, mutect2, varscan2
- FAM189A2 | c.555G>T p.V185= | Silent (SNP) | VAF 12/238 reads (5%) | catalogued as COSV99974798; called by muse, mutect2
- FGFR2 | c.372C>T p.V124= | Silent (SNP) | VAF 39/440 reads (9%) | catalogued as COSV100335507; called by muse, mutect2
- GPC4 | c.1137C>T p.G379= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as COSV100895419; called by muse, mutect2, varscan2
- HCN1 | c.1878G>A p.V626= | Silent (SNP) | VAF 38/353 reads (11%) | catalogued as COSV100299100; called by muse, mutect2
- HECW1 | c.4158A>G p.E1386= | Silent (SNP) | VAF 76/133 reads (57%) | catalogued as COSV101222981; called by muse, mutect2, varscan2
- HOXB1 | c.783C>T p.R261= | Silent (SNP) | VAF 54/170 reads (32%) | catalogued as rs765879162, COSV53317126; called by muse, mutect2, varscan2
- HSPA2 | c.210C>T p.D70= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as COSV99904749; called by muse, mutect2, varscan2
- IFIT5 | c.1321C>T p.L441= | Silent (SNP) | VAF 42/155 reads (27%) | catalogued as COSV100877928; called by muse, varscan2
- IFT80 | c.693C>T p.P231= | Silent (SNP) | VAF 4/54 reads (7%) | catalogued as COSV100424511; called by muse, mutect2
- ITGAD | c.486C>T p.D162= | Silent (SNP) | VAF 4/35 reads (11%) | catalogued as rs1376964708, COSV101210363; called by muse, mutect2, varscan2
- LOX | c.855C>T p.S285= | Silent (SNP) | VAF 64/125 reads (51%) | catalogued as COSV99140571, COSV99140609; called by muse, mutect2, varscan2
- LPA | c.5403C>T p.S1801= | Silent (SNP) | VAF 58/1024 reads (6%) | catalogued as COSV100306304; called by muse, mutect2
- MAN2A2 | c.1839C>T p.T613= | Silent (SNP) | VAF 27/77 reads (35%) | catalogued as rs778574745, COSV100847779; called by muse, mutect2, varscan2
- MKI67 | c.7353G>A p.E2451= | Silent (SNP) | VAF 15/334 reads (4%) | called by muse, mutect2
- MOV10 | c.2106G>C p.L702= | Silent (SNP) | VAF 10/70 reads (14%) | catalogued as COSV99588108; called by muse, mutect2
- MRC1 | c.1149C>T p.I383= | Silent (SNP) | VAF 33/113 reads (29%) | catalogued as COSV99519317; called by muse, mutect2, varscan2
- MSS51 | c.102C>T p.T34= | Silent (SNP) | VAF 10/70 reads (14%) | catalogued as rs1465223088, COSV100200100; called by muse, mutect2, varscan2
- MTHFD1L | c.1338C>T p.V446= | Silent (SNP) | VAF 158/742 reads (21%) | catalogued as COSV100799438; called by muse, varscan2
- MUC16 | c.9309A>G p.E3103= | Silent (SNP) | VAF 169/439 reads (38%) | catalogued as COSV101198630; called by muse, mutect2, varscan2
- NIBAN1 | c.2754G>A p.Q918= | Silent (SNP) | VAF 260/500 reads (52%) | catalogued as COSV100836301; called by muse, mutect2, varscan2
- NOS1 | c.600G>A p.G200= | Silent (SNP) | VAF 26/371 reads (7%) | catalogued as COSV100500170; called by muse, mutect2
- PHC1 | c.36C>T p.T12= | Silent (SNP) | VAF 5/58 reads (9%) | catalogued as COSV101418533, COSV70417469; called by muse, mutect2
- POTEF | c.1650C>T p.V550= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as rs1349264633, COSV100664662, COSV100665212; called by muse, mutect2, varscan2
- PRTG | c.2211C>T p.S737= | Silent (SNP) | VAF 22/210 reads (10%) | catalogued as COSV101221311; called by muse, varscan2
- REEP1 | c.564C>T p.S188= | Silent (SNP) | VAF 99/107 reads (93%) | catalogued as COSV99382566; called by muse, varscan2
- SAGE1 | c.348G>A p.R116= | Silent (SNP) | VAF 12/154 reads (8%) | catalogued as COSV100186823, COSV61013141; called by muse, mutect2
- SUSD1 | c.264C>T p.H88= | Silent (SNP) | VAF 87/192 reads (45%) | catalogued as COSV100813198; called by muse, mutect2, varscan2
- SYNE1 | c.15261G>A p.R5087= (on ENST00000367255 / NM_182961.4; = p.R5016= on NM_033071.3) | Silent (SNP) | VAF 22/228 reads (10%) | catalogued as COSV99556090; called by muse, varscan2
- TBRG4 | c.207G>A p.E69= | Silent (SNP) | VAF 51/196 reads (26%) | catalogued as COSV99345255; called by muse, mutect2, varscan2
- TLR3 | c.508C>T p.L170= | Silent (SNP) | VAF 40/133 reads (30%) | catalogued as COSV99710866; called by muse, mutect2, varscan2
- TNKS1BP1 | c.4545C>T p.A1515= | Silent (SNP) | VAF 18/83 reads (22%) | catalogued as rs1471009078, COSV100835857; called by muse, mutect2, varscan2
- TRPV5 | c.246G>A p.A82= | Silent (SNP) | VAF 63/416 reads (15%) | catalogued as rs766993567, COSV99520188; called by muse, varscan2
- TUBGCP6 | c.270G>A p.E90= | Silent (SNP) | VAF 10/154 reads (6%) | catalogued as COSV99352176; called by muse, mutect2
- UBE3C | c.1767A>G p.Q589= | Silent (SNP) | VAF 26/343 reads (8%) | catalogued as rs766565908, COSV100779839; called by muse, mutect2
- UMPS | c.411G>A p.E137= | Silent (SNP) | VAF 122/316 reads (39%) | catalogued as COSV99228810; called by muse, varscan2
- USP29 | c.2721G>A p.V907= | Silent (SNP) | VAF 14/246 reads (6%) | catalogued as COSV99517800; called by muse, mutect2
- VPS52 | c.2151G>A p.K717= | Silent (SNP) | VAF 47/176 reads (27%) | catalogued as rs758493602, COSV101408755; called by muse, mutect2, varscan2
- ZC3H12A | c.948C>A p.I316= | Silent (SNP) | VAF 4/27 reads (15%) | called by mutect2, varscan2
- ZFP69 | c.1191C>T p.H397= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as COSV101018130; called by muse, mutect2, varscan2
- ZIC3 | c.1398C>T p.Y466= | Silent (SNP) | VAF 41/222 reads (18%) | catalogued as rs1331228285, COSV99798529; called by muse, mutect2, varscan2
- ZNF619 | c.1455C>G p.L485= | Silent (SNP) | VAF 44/69 reads (64%) | catalogued as COSV100123094; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65502881 A>G | 5'Flank (SNP) | VAF 6/30 reads (20%) | catalogued as rs907652755; called by mutect2, varscan2
- DCHS2 | n.3104G>T | RNA (SNP) | VAF 12/204 reads (6%) | catalogued as COSV100251124; called by muse, mutect2
- DPP6 | c.627+20951C>T | Intron (SNP) | VAF 316/1623 reads (19%) | catalogued as COSV100123661; called by muse, varscan2
- DPP6 | c.627+20996C>T | Intron (SNP) | VAF 223/987 reads (23%) | catalogued as COSV100123662; called by muse, varscan2
